Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4164, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4164-01A (Primary Tumor).

[page 1 of 2]
Other Related Data:

Billing Type:

Financial Number |

Clinical Diagnosis & History:

with bilateral multifocal enhancing renal masses and liver mass.

Specimens Submitted:

1: SP: Segment four of liver nodule

2: SP: Left kidney and adrenal

DIAGNOSIS:

- 1) LIVER, SEGMENT 4, NODULE; SEGMENTECTOMY:
- HYPERPLASIA OF LIVER PARECHIMA WITH A VAGUE NODULAR PATTERN IN THIS SAMPLE. MILD STEATOSIS.
- 2) KIDNEY AND ADRENAL GLAND, LEFT; RADICAL NEPHRECTOMY:
- RENAL CELL CARCINOMA, CLEAR CELL TYPE, NUCLEAR GRADE II/IV. THE PATTERN OF GROWTH IS ACINAR. THE TUMOR GREATEST DIAMETER IS 13.5 CM. THE TUMOR EXTENDS THROUGH THE RENAL CAPSULE AND INTO THE HILUM OF THE KIDNEY, BUT IS CONFINED WITHIN GEROTA'S FASCIA. NO INVASION OF THE RENAL VEIN IS IDENTIFIED. ALL SURGICAL MARGINS ARE FREE OF TUMOR. THE NON-NEOPLASTIC KIDNEY IS UNREMARKABLE. THE ADRENAL GLAND IS UNREMARKABLE.

Gross Description:

- 1) The specimen is received fresh for frozen section, labeled "Segment 4 of Liver Nodule". It consists of a 1 x 0.9 x 0.8 cm, brown-tan, soft tissue. Entirely frozen.

[page 2 of 2]
Summary of Sections:
FSC - frozen section control

2) The specimen is received fresh, labeled, "Left Kidney and Adrenal". It consists of a kidney, adrenal gland, an 8.2 cm long segment of ureter. The specimen measures 21.0 x 12.0 x 9.5 cm and weighs 950 grams. Bivalving reveals a large ill-defined tumor arising in the upper pole and measuring 13.5 x 8.0 x 7.8 cm with one satellite nodule situated 0.6 cm from the main mass, measuring 1.2 cm in greatest dimension. The tumor is rimmed by golden, yellow-tan tissue with extensively hemorrhagic and centrally fibrotic. Adrenal gland does not appear to be grossly involved. Sectioning of the perinephric fat does not reveal gross extension of tumor through the renal capsule. The tumor extends to the upper peripheral portion of renal pelvis and renal vein does not appear to be grossly involved. Representative sections of tumor with surgical margin is submitted.

Summary of Sections:

VM - vessel margin
UM - ureteral margin
K - kidney
SN - satellite nodule
RP - renal pelvis
P - pelvis
A - adrenal
T - tumor

Summary of Sections:

Part	Sect.	Site	Blocks	Pieces	All
1	FSC		1	1	Y
2	A		1	1	
	K		1	1	
	P		1	1	
	RP		1	1	
	SN		1	1	
	T		9	M	
	UM		1	M	
	VM		1	M	

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: BENIGN HEPATOCELLULAR LESION.
(RG)
PERMANENT DIAGNOSIS: SAME.

Source: NCI Genomic Data Commons file 6d2384ae-41b2-4f4e-b2ba-94d612da6fc4 (TCGA-BP-4164.B598F376-C31A-4D96-A518-E277024B2700.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).